Somatic mutation profile of tumor specimen 0DVSC0 from CCDI case PBCNGP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Craniopharyngioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,016 days).
Specimen 0DVSC0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e39d7e6-49e7-497b-b260-189a7eb2c9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSCD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84d4a3e4-f02c-4a44-bc71-783ea6d78e71

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 112/359 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZNF648 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 80/355 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1216361753; called by muse, mutect2, varscan2
- MYH13 | c.2900A>G p.K967R | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- NES | c.2893A>G p.S965G | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5A1 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 71/268 reads (26%) | called by muse, mutect2, varscan2
- ROCK2 | c.4055C>G p.P1352R | Missense Mutation (SNP) | VAF 14/387 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2
- FGFRL1 | c.339C>T p.T113= | Silent (SNP) | VAF 26/316 reads (8%) | catalogued as rs200350712; called by muse, mutect2
- OR2H1 | c.363C>T p.Y121= | Silent (SNP) | VAF 86/340 reads (25%) | catalogued as rs753680027; called by muse, mutect2, varscan2
- SCAF4 | c.1959A>G p.E653= | Silent (SNP) | VAF 79/413 reads (19%) | called by muse, mutect2, varscan2
